Somatic mutation profile of tumor specimen 0DSCP5 from CCDI case PBCHEY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cerebrum; Age at diagnosis: 9.8 years (3,597 days).
Specimen 0DSCP5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac70c63e-dc17-44fe-999d-ca7596d641e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSCOV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b3bf246-93a0-4e50-85ee-8552f1fdaa81

The open-access MAF lists 8 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 3, RNA 2, Missense Mutation 1, 5'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/619 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 25/684 reads (4%) | called by muse, mutect2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 8/87 reads (9%) | called by muse, varscan2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 14/187 reads (7%) | called by muse, mutect2
- LINC02694 | n.552G>A | RNA (SNP) | VAF 14/179 reads (8%) | catalogued as rs768118261; called by muse, mutect2
- NSFL1C | c.786-60T>A | Intron (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 26/176 reads (15%) | called by muse, varscan2
- ZNF277 | c.801+32A>T | Intron (SNP) | VAF 13/361 reads (4%) | called by muse, mutect2
